TCGA case TCGA-BP-5183 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64aa0dd1-a80e-401e-96df-60d121d2cbec

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,881 days); Year of diagnosis: 2007; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 58.5 years (21,366 days); Days to diagnosis: 485 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 522 days (1.4 years); Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 485 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 485 days (1.3 years).
- Days to follow up: 1,102 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,291 days (3.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Leukocytes: Normal.
- Platelets: Low.
- Calcium: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-5183-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-BP-5183-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-BP-5183-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-BP-5183-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-5183-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Lymph nodes examined: No.
- Follow-up form: New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,291 days; disease-specific survival: no event (censored), 1,291 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 485 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BP-5183-01A-01D-1423-01): tumor purity 0.67, ploidy 1.85, whole-genome doublings 0.
